Somatic mutation profile of tumor specimen MMRF_1963_1_BM_CD138pos (aliquot MMRF_1963_1_BM_CD138pos_T1_KBS5U_L06457) from MMRF case MMRF_1963, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.3 years (23,470 days).
Specimen MMRF_1963_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d54ecff9-d421-47db-8c20-a5be24c80247.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1963_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1963_1_PB_Whole_C3_KBS5U_L06485; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c4a66ec-602d-45f9-ab17-4f0474841819

The open-access MAF lists 56 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 3'UTR 13, Silent 10, Intron 5, Splice Site 4, Frame Shift Del 3, 5'UTR 2, 3'Flank 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.12661C>T p.R4221C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68943091; called by muse, mutect2, varscan2
- ARHGEF28 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs779778189; called by muse, mutect2, varscan2
- DUOX2 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs573487375, COSV101199756; called by muse, mutect2, varscan2
- IGHJ5 | c.26del p.G9Efs*? | Frame Shift Del (DEL) | VAF 30/48 reads (63%) | catalogued as rs782276869; called by pindel, varscan2
- IGHV3-30 | c.162C>G p.H54Q | Missense Mutation (SNP) | VAF 72/380 reads (19%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.43); catalogued as rs748862973; called by muse, varscan2
- IGHV3-30 | c.152A>T p.Y51F | Missense Mutation (SNP) | VAF 70/363 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs373898441; called by muse, varscan2
- IKZF3 | c.1450_1451del p.M484Vfs*7 | Frame Shift Del (DEL) | VAF 114/275 reads (41%) | catalogued as rs1235616883; called by mutect2, pindel, varscan2
- ITIH5 | c.1664A>G p.D555G | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV104376342; called by muse, mutect2, varscan2
- OVCH2 | c.902-1G>A p.X301_splice | Splice Site (SNP) | VAF 46/97 reads (47%) | catalogued as rs1297429357; called by muse, mutect2, varscan2
- OXTR | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as COSV57479433; called by muse, mutect2
- POLR3G | c.222T>G p.F74L | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as COSV67625262; called by muse, mutect2, varscan2
- SF3B3 | c.2077T>A p.Y693N | Missense Mutation (SNP) | VAF 47/59 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56788800; called by muse, mutect2, varscan2
- CCDC144A | c.1758C>A p.N586K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.035); called by mutect2, varscan2
- CEP350 | c.1264del p.S422Vfs*11 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | called by mutect2, pindel
- CFAP57 | c.190T>C p.S64P | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.078); called by muse, mutect2
- DDIT4L | c.-50+1G>A | Splice Site (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- DIAPH3 | c.859G>A p.D287N (on ENST00000400324 / NM_001042517.2; = p.D24N on NM_030932.3) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KCP | c.409+2_409+19del p.X137_splice | Splice Site (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- MAX | c.296-10_300del p.X99_splice | Splice Site (DEL) | VAF 46/60 reads (77%) | called by mutect2, pindel, varscan2
- RELCH | c.3073C>A p.P1025T | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2
- SRCIN1 | c.2313G>T p.E771D (on ENST00000621492; = p.E737D on NM_025248.3) | Missense Mutation (SNP) | VAF 96/212 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF516 | c.3281G>T p.R1094L | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CSMD3 | c.7797A>T p.G2599= (on ENST00000297405 / NM_001363185.1; = p.G2495= on NM_052900.3) | Silent (SNP) | VAF 65/81 reads (80%) | called by muse, mutect2, varscan2
- DNM2 | c.633C>T p.D211= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs200191870; ClinVar: likely benign / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- GPC3 | c.81G>C p.P27= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs1484069125, COSV100892796; called by muse, mutect2
- IGFBPL1 | c.441C>A p.R147= | Silent (SNP) | VAF 56/178 reads (31%) | called by muse, mutect2, varscan2
- IGHV3-30 | c.228T>C p.N76= | Silent (SNP) | VAF 74/375 reads (20%) | catalogued as rs527801638; called by muse, varscan2
- IGHV3-30 | c.135A>G p.G45= | Silent (SNP) | VAF 86/376 reads (23%) | called by muse, varscan2
- NOTCH3 | c.2859C>T p.G953= | Silent (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- OR10AG1 | c.441A>C p.V147= | Silent (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- SORCS3 | c.3534C>T p.P1178= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV63803640; called by muse, mutect2
- VPS53 | c.921A>C p.P307= (on ENST00000571805 / NM_001366253.2; = p.P278= on NM_018289.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/119 reads (35%) | called by muse, mutect2, varscan2
- AGGF1 | c.*1944G>A | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.2772+109C>T | Intron (SNP) | VAF 5/61 reads (8%) | catalogued as rs1378668292; called by muse, mutect2
- ATAD3B | c.*1051C>G | 3'UTR (SNP) | VAF 38/42 reads (90%) | called by muse, mutect2, varscan2
- CACNG3 | c.-78C>T | 5'UTR (SNP) | VAF 35/97 reads (36%) | catalogued as COSV50073867; called by muse, mutect2, varscan2
- CDCA7L | c.*33T>C | 3'UTR (SNP) | VAF 148/262 reads (56%) | catalogued as rs369148835; called by muse, mutect2, varscan2
- CDCP1 | c.*2131A>G | 3'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- COG5 | c.*115T>G | 3'UTR (SNP) | VAF 89/176 reads (51%) | called by muse, mutect2, varscan2
- EXOC7 | c.808+438A>G | Intron (SNP) | VAF 99/206 reads (48%) | called by muse, mutect2, varscan2
- HSP90AA4P | n.967A>C | RNA (SNP) | VAF 56/108 reads (52%) | called by muse, mutect2
- IRF2BP2 | c.*1151T>C | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- MARCHF7 | c.*3652A>G | 3'UTR (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- OSTC | c.*59_*78del | 3'UTR (DEL) | VAF 26/82 reads (32%) | called by mutect2, pindel, varscan2
- PDLIM2 | chr8:22596262 G>A | 3'Flank (SNP) | VAF 56/62 reads (90%) | called by muse, mutect2, varscan2
- POLR3B | c.2985-1193T>C | Intron (SNP) | VAF 34/38 reads (89%) | called by muse, mutect2
- PREPL | c.-830C>A | 5'UTR (SNP) | VAF 21/82 reads (26%) | called by muse, mutect2, varscan2
- RDH16 | c.*440C>A | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- SLC35E2B | c.*917T>C | 3'UTR (SNP) | VAF 6/8 reads (75%) | catalogued as rs1109645; called by muse, mutect2, varscan2
- SLC35F3 | c.402-2622G>A | Intron (SNP) | VAF 3/14 reads (21%) | catalogued as rs940920342; called by muse, mutect2
- SNRK | c.*1021G>A | 3'UTR (SNP) | VAF 24/60 reads (40%) | catalogued as rs1419939882; called by muse, mutect2, varscan2
- STMN4 | chr8:27235751 A>G | 3'Flank (SNP) | VAF 4/31 reads (13%) | called by mutect2, varscan2
- TMEM132D | c.*1633T>A | 3'UTR (SNP) | VAF 48/60 reads (80%) | called by mutect2, varscan2
- VGLL1 | c.688+76A>G | Intron (SNP) | VAF 24/27 reads (89%) | called by muse, mutect2, varscan2
- VPS41 | c.*10C>T | 3'UTR (SNP) | VAF 53/194 reads (27%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866571 G>A | 5'Flank (SNP) | VAF 43/115 reads (37%) | called by muse, mutect2, varscan2
